Somatic mutation profile of tumor specimen C3L-07548-01 (aliquot CPT0482890009) from CPTAC case C3L-07548, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 81.7 years (29,840 days).
Specimen C3L-07548-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a5d64e5-1335-48d2-a338-91d154f71c35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07548-31 (Blood Derived Normal), aliquot CPT0482950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22bb9541-768f-42b3-9bdc-d0f7ce3fde7e

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 28, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 182/375 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CMSS1 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV70436282; called by muse, mutect2, varscan2
- CNTN2 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 99/469 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as rs748302990; called by muse, mutect2, varscan2
- EPHA5 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 89/490 reads (18%) | catalogued as COSV56633312; called by muse, mutect2, varscan2
- GABBR1 | c.2521A>G p.I841V | Missense Mutation (SNP) | VAF 87/585 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as rs138053745; called by muse, mutect2, varscan2
- OR5C1 | c.549C>A p.C183* | Nonsense Mutation (SNP) | VAF 104/428 reads (24%) | catalogued as COSV65455981; called by muse, mutect2, varscan2
- PDGFRL | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs373035421; called by muse, mutect2, varscan2
- PPL | c.3649G>C p.E1217Q | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.528); catalogued as COSV52171037; called by muse, mutect2, varscan2
- RIN3 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 78/402 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255173953; called by muse, mutect2, varscan2
- TP53INP2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs763974095, COSV100873682; called by muse, mutect2, varscan2
- ZFHX4 | c.9615G>T p.E3205D | Missense Mutation (SNP) | VAF 79/514 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV51471914, COSV99268038; called by muse, varscan2
- ZNF260 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 87/372 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs767438245; called by muse, mutect2, varscan2
- AGFG2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 92/414 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALKBH8 | c.783T>G p.D261E | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- C20orf194 | c.1326_1329del p.D442Efs*8 | Frame Shift Del (DEL) | VAF 51/281 reads (18%) | called by mutect2, pindel, varscan2
- CHD6 | c.7579G>A p.A2527T | Missense Mutation (SNP) | VAF 93/400 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC6A | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 72/376 reads (19%) | called by muse, mutect2, varscan2
- DUSP1 | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPPK1 | c.2969G>A p.R990K | Missense Mutation (SNP) | VAF 121/777 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HEG1 | c.3332_3342dup p.V1115Sfs*15 | Frame Shift Ins (INS) | VAF 46/218 reads (21%) | called by mutect2, varscan2
- ING1 | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 92/578 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); called by mutect2, varscan2
- ING1 | c.229_236del p.S77Pfs*207 | Frame Shift Del (DEL) | VAF 96/621 reads (15%) | called by mutect2, pindel, varscan2
- KMT2C | c.519T>G p.I173M | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MMP15 | c.1669A>T p.M557L | Missense Mutation (SNP) | VAF 119/536 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- NBEA | c.5219G>C p.G1740A | Missense Mutation (SNP) | VAF 113/601 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- NGEF | c.1967A>G p.H656R | Missense Mutation (SNP) | VAF 69/384 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1F1 | c.920G>T p.R307M | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIP4K2C | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RPL18A | c.435C>G p.F145L | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SBF2 | c.1669A>G p.I557V | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SCEL | c.1751A>G p.Y584C (on ENST00000349847 / NM_144777.3; = p.Y564C on NM_003843.4) | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SMIM23 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF124 | c.503A>G p.H168R (on ENST00000543802 / NM_001297568.1; = p.H106R on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 186/414 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF787 | c.230A>T p.H77L | Missense Mutation (SNP) | VAF 81/362 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CD99 | c.258C>G p.S86= | Silent (SNP) | VAF 78/410 reads (19%) | catalogued as COSV101153077, COSV101153303; called by mutect2, varscan2
- GRIN2B | c.3453G>A p.L1151= | Silent (SNP) | VAF 110/519 reads (21%) | called by muse, mutect2, varscan2
- GUCA1C | c.54G>A p.E18= | Silent (SNP) | VAF 105/430 reads (24%) | called by muse, mutect2, varscan2
- IGSF21 | c.1050C>A p.P350= | Silent (SNP) | VAF 126/259 reads (49%) | called by muse, mutect2, varscan2
- MAST4 | c.5595G>A p.K1865= (on ENST00000403625 / NM_001164664.2; = p.K1676= on NM_015183.3) | Silent (SNP) | VAF 98/416 reads (24%) | called by muse, mutect2, varscan2
- NELFB | c.1101C>T p.V367= | Silent (SNP) | VAF 81/346 reads (23%) | called by muse, mutect2, varscan2
- PHIP | c.3933T>C p.N1311= | Silent (SNP) | VAF 67/272 reads (25%) | catalogued as rs1458484801; called by muse, mutect2, varscan2
- RBM12B | c.1530A>G p.L510= | Silent (SNP) | VAF 65/409 reads (16%) | catalogued as rs781146046; called by muse, mutect2, varscan2
- SERINC5 | c.1017C>T p.D339= | Silent (SNP) | VAF 84/357 reads (24%) | catalogued as rs370968698; called by muse, mutect2, varscan2
- TMEM35A | c.82C>T p.L28= | Silent (SNP) | VAF 73/336 reads (22%) | called by muse, mutect2, varscan2
- TP53INP2 | c.174C>A p.G58= | Silent (SNP) | VAF 64/406 reads (16%) | called by muse, mutect2, varscan2
- VSTM4 | c.111G>A p.L37= | Silent (SNP) | VAF 105/391 reads (27%) | called by muse, mutect2, varscan2
